Somatic mutation profile of tumor specimen BA2153D (aliquot aq-BA2153D) from BEATAML1.0 case 2301, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, minimal differentiation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 70.9 years (25,886 days).
Specimen BA2153D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8e079ecf-3b91-4e3b-92c4-22c233bda042.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2458D (Solid Tissue Normal), aliquot aq-BA2458D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2beb231-e96d-4519-9cc7-bb1671f49dfe

The open-access MAF lists 10 somatic variants for this specimen: 5 protein-altering or splice-affecting, 5 silent.
By variant classification: Silent 5, Missense Mutation 3, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FRMPD2 | c.1630G>T p.E544* | Nonsense Mutation (SNP) | VAF 7/94 reads (7%) | catalogued as COSV59717855, COSV59721961; called by muse, mutect2
- KALRN | c.136G>A p.V46M | Missense Mutation (SNP) | VAF 18/358 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs926123706, COSV53752228; called by muse, mutect2
- MYH13 | c.5641T>A p.S1881T | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV52837022, COSV99353665; called by muse, mutect2, varscan2
- PEAR1 | c.1701C>A p.C567* | Nonsense Mutation (SNP) | VAF 3/33 reads (9%) | catalogued as rs1558141698; called by muse, mutect2
- USP34 | c.9608G>T p.C3203F | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT tolerated (0.49); PolyPhen benign (0.136); called by muse, mutect2
- H1-10 | c.198G>T p.S66= | Silent (SNP) | VAF 6/83 reads (7%) | called by muse, mutect2
- ILVBL | c.156G>T p.R52= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as rs952339854, COSV99655263; called by muse, mutect2
- KRT33B | c.21G>T p.L7= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV99290760; called by muse, mutect2
- PDP2 | c.555C>A p.P185= | Silent (SNP) | VAF 3/46 reads (7%) | catalogued as COSV61240282; called by muse, mutect2
- RCC1L | c.6G>T p.A2= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as rs1276382694; called by muse, mutect2
